Gene-level copy-number profile of tumor specimen TCGA-13-1499-01A from TCGA case TCGA-13-1499, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.6 years (20,668 days).
Specimen TCGA-13-1499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.55fae161-727b-441c-97ad-8bbc71cfdc32.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1499-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3265ae29-42cb-49b4-b9c0-b69dd360f6a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 4,100; copy number 2: 23,078; copy number 3: 19,023; copy number 4: 11,325; copy number 5: 1,515; copy number 6: 299; copy number 9: 279; copy number 11: 49; copy number 16: 2; copy number 18: 8; copy number 25: 64; copy number 26: 9; copy number 29: 8; copy number 73: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1499-01A-01D-0472-01): tumor purity 0.42, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,247 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,772,904–189,897,276, 419 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:38,382,364–38,560,939, 8 genes, copy number 18: AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.
- chr8:49,536,386–56,559,823, 97 genes, copy number 16–73 (broad region; genes not listed).
- chr8:93,134,095–98,942,827, 115 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:106,215,763–145,066,685, 578 genes, copy number 6–9 (broad region; genes not listed).
- chr10:130,505,106–133,761,125, 85 genes, copy number 5 (broad region; genes not listed).
- chr11:118,883,892–125,164,609, 209 genes, copy number 5 (broad region; genes not listed).
- chr11:125,188,115–125,191,404, 1 gene, copy number 5: AP001007.3.
- chr12:66,767–25,648,579, 664 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:20,028,239–21,550,373, 49 genes, copy number 11: GPR139, AC092132.2, AC092132.1, SNRPEP3, GP2, UMOD, PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1, DNAH3, AC008551.1, TMEM159, AF001550.1, ZP2, ANKS4B, CRYM, AF001550.2, CRYM-AS1, AC008740.1, SNX29P1, AC008740.2, NPIPB3, SMG1P3, MIR3680-1, AC005632.6, SLC7A5P2, AC005632.5, AC005632.2, AC005632.4.
- chr20:87,250–675,802, 22 genes, copy number 5: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2.

Autosomal genes at a single copy (total copy number 1): 2,107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
